CCDI case PBCKSJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/818a7fd0-1822-4a1f-a9bf-b4fa857dabe5

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Upper respiratory tract, NOS; Age at diagnosis: 4.1 years (1,504 days).

Biospecimens (3 samples)
- Samples 0DU7A2, 0DU7AC (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU7A7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
